Surgical pathology report (de-identified scan), TCGA case TCGA-18-5595, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Princess Margaret Hospital (Canada), specimen TCGA-18-5595-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Lymph-Node: ST11 INTERLOBAR
2. Lung: RIGHT LOWER LOBE

DIAGNOSIS

1. Lymph node, biopsy (ST11 interlobar):
- Lymph node, negative for malignancy
2. Lung, resection (right lower lobectomy):
- a) Invasive moderately differentiated squamous cell carcinoma, with:
- i) Greatest dimension = 3.5 cm
- ii) Visceral pleural and vascular invasion not identified
- iii) Lymphatic permeation present
- iv) Resection margins negative for tumor
- v) Two lobar lymph nodes, negative for malignancy (0/2)
- b) Lung tissue with patchy non-specific chronic inflammation and organizing pneumonia

SYNOPTIC DATA

Specimen Type:	Lobectomy
Laterality:	Right
Tumor Site:	RLL
Tumor Size:	Greatest dimension: 3.5 cm
Histologic Type:	Squamous cell carcinoma
Histologic Grade:	G2: Moderately differentiated
Pathologic Staging (pTNM):	pT2: Tumor with any of the following
features of size or extent:	greater than 3 cm in greatest dimension;
involves main bronchus,	2 cm or more distal to the carina; invades the
visceral pleura; associated with	atelectasis or obstructive pneumonitis
that extends to the hilar region but	does not involve the entire lung
	pN0: No regional lymph node

[page 2 of 3]
metastasis

Margins:	pMX: Cannot be assessed
carcinoma	Margins uninvolved by invasive
	Distance of invasive carcinoma from
closest margin: 2 cm	Margin: (vascular)
Direct Extension of Tumor:	None identified
Blood Vessel Invasion:	Absent
Lymphatic (Small Vessel) Invasion (L):	Present
Additional Pathologic Findings:	Inflammation (type): patchy chronic
inflammation and organizing pneumonia	

COMMENT

Sections show a moderately differentiated, focally keratinizing squamous cell carcinoma demonstrating extensive tumor necrosis. Pleural and vascular invasion are not identified. Lymphatic invasion is present focally (confirmed by D2-40 immunohistochemical staining for lymphatic endothelium), but lymph node metastases are not identified. The patient's history of previous oropharyngeal squamous carcinoma is noted, but slides are not available for comparison. Assuming the present tumor to be a primary pulmonary tumor rather than a metastatic lesion, the pathologic stage is assessed as pT2N0.

GROSS DESCRIPTION

1. The specimen is labeled with the patient's name and as "Lymph-Node: ST11 Interlobar".

One piece of black, firm tissue measuring 0.7 x 0.4 x 0.3 cm.

1A submitted in toto

2. The specimen is labeled with the patient's name and as "LUNG: Right lower lobe".

Resection specimen: Right lower lung lobectomy measuring 13.5 x 10.0 x 2 cm

[page 3 of 3]
[REDACTED]

[REDACTED]

[REDACTED]

Staple line: 9.5 cm in length
Pleural surface: Intact, focally hemorrhagic and smooth.
Tumour:
Number of tumors: One
Measurements: 3.5 x 2.5 x 3.0 cm.
Location: Centrally within the lobe
Extent of invasion: Into bronchial wall
Distance from resection margins: 2.5 cm from the bronchial resection margin; 2.4 cm from the closest stapled parenchymal resection margin; 0.7 cm from the closest pleural surface; 2.0 cm from the vascular margins
Descriptive characteristics: White in colour and partially necrotic; firm in consistency; well delineated
Lung parenchyma: Grossly unremarkable
Other lesions: No
Lymph Nodes: Two lobar lymph nodes are identified measuring 0.7 to 1.7 cm in greatest dimension.
Frozen Section: No
Tissue Banking: Yes

Representative sections are submitted as follows:

2A shavings from stapled resection margin
2B bronchial resection margin, en face
2C vascular margins, en face
2D tumor with closest pleural surface
2E tumor showing invasion into bronchial wall
2F-2G tumor
2H-2I normal lung parenchyma
2J-2K one bisected lymph node, per block

[REDACTED]

Source: NCI Genomic Data Commons file 5484ea3d-ec74-4cd7-b13b-a953e9a2d2c4 (TCGA-18-5595.3CA67814-08D3-4146-985D-B6608B3A7FE6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).